Somatic mutation profile of tumor specimen TCGA-BG-A186-01A (aliquot TCGA-BG-A186-01A-11D-A12J-09) from TCGA case TCGA-BG-A186, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 61.2 years (22,370 days).
Specimen TCGA-BG-A186-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b1f1a103-6264-4b80-ba0b-cffdbe54e824.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BG-A186-10A (Blood Derived Normal), aliquot TCGA-BG-A186-10A-01D-A12J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3c951409-782d-4f7f-b6e0-fd1d470439c2

The open-access MAF lists 34 somatic variants for this specimen: 24 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 8, Frame Shift Del 3, Frame Shift Ins 1, 3'UTR 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTCF | c.1129C>T p.R377C | Missense Mutation (SNP) | VAF 69/100 reads (69%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50461516; called by muse, mutect2, varscan2
- PIK3CA | c.1035T>A p.N345K | Missense Mutation (SNP) | VAF 29/84 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs121913284, COSV55873276; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.870del p.E291Kfs*16 | Frame Shift Del (DEL) | VAF 77/230 reads (33%) | catalogued as rs886041332, CD110170, COSV64306449; ClinVar: pathogenic; called by pindel, varscan2
- PTEN | c.956_959del p.T319Kfs*24 | Frame Shift Del (DEL) | VAF 56/138 reads (41%) | catalogued as rs398123330, COSV64288731; ClinVar: pathogenic; called by pindel, varscan2
- ABCA2 | c.386G>A p.R129H (on ENST00000614293; = p.R99H on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.029); catalogued as rs752161404, COSV55803654; called by muse, mutect2, varscan2
- ADCY5 | c.2165G>A p.R722H | Missense Mutation (SNP) | VAF 55/140 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.745); catalogued as rs1553725039, COSV59198464; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AKR1B15 | c.604C>T p.P202S | Missense Mutation (SNP) | VAF 61/170 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs748600907, COSV71152771; called by muse, mutect2, varscan2
- COMMD5 | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs542013865, COSV57385339; called by muse, mutect2, varscan2
- EPHA10 | c.712G>A p.G238R | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766000675, COSV57627112; called by muse, mutect2, varscan2
- FRA10AC1 | c.592C>T p.H198Y | Missense Mutation (SNP) | VAF 94/283 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs149181398; called by muse, mutect2, varscan2
- INVS | c.2306C>T p.P769L | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs1477368510, COSV52441278; called by muse, mutect2, varscan2
- KIF20B | c.2977del p.R993Vfs*12 (on ENST00000371728 / NM_001284259.2; = p.R953Vfs*12 on NM_016195.4) | Frame Shift Del (DEL) | VAF 26/79 reads (33%) | catalogued as COSV53315201; called by mutect2, pindel, varscan2
- NCSTN | c.455A>T p.Y152F | Missense Mutation (SNP) | VAF 191/362 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.703); catalogued as COSV54191631; called by muse, mutect2, varscan2
- OR56B4 | c.897G>T p.R299S | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV57205544; called by muse, mutect2, varscan2
- PAIP1 | c.496T>G p.L166V | Missense Mutation (SNP) | VAF 84/181 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.247); catalogued as COSV59087764; called by muse, mutect2, varscan2
- PKD2L1 | c.1120C>T p.L374F | Missense Mutation (SNP) | VAF 74/194 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as COSV58398718; called by muse, mutect2
- POGZ | c.3328C>T p.R1110W | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV51853248; called by muse, mutect2, varscan2
- SPOCK2 | c.956G>A p.R319H | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as rs41304635; called by muse, mutect2, varscan2
- ST3GAL5 | c.421C>T p.H141Y (on ENST00000377332; = p.H181Y on NM_003896.4) | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT tolerated (1); PolyPhen possibly damaging (0.886); catalogued as rs750698842, COSV60387047; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBG1 | c.996+1G>A p.X332_splice | Splice Site (SNP) | VAF 41/130 reads (32%) | catalogued as COSV52222871; called by muse, mutect2, varscan2
- UBASH3A | c.942C>A p.S314R | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs147873921, COSV52315986; called by muse, mutect2, varscan2
- UNC13D | c.2219C>T p.T740M | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs761013333, COSV52887250; called by muse, mutect2, varscan2
- WDR24 | c.445G>A p.E149K (on ENST00000248142; = p.E87K on NM_032259.4) | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as COSV50204527; called by muse, mutect2, varscan2
- TNIK | c.3621dup p.I1208Yfs*12 | Frame Shift Ins (INS) | VAF 64/194 reads (33%) | called by mutect2, pindel, varscan2
- ABCD1 | c.213C>T p.F71= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV54387710; called by muse, varscan2
- ADAM15 | c.1527C>T p.G509= | Silent (SNP) | VAF 44/144 reads (31%) | catalogued as rs750901317, COSV55126187; called by muse, mutect2, varscan2
- CFH | c.774G>A p.P258= | Silent (SNP) | VAF 87/170 reads (51%) | catalogued as rs146074007; called by muse, mutect2, varscan2
- FBXO5 | c.204T>A p.I68= | Silent (SNP) | VAF 76/174 reads (44%) | catalogued as COSV57671605; called by muse, varscan2
- FRA10AC1 | c.591G>A p.E197= | Silent (SNP) | VAF 94/284 reads (33%) | catalogued as COSV63273809; called by muse, mutect2, varscan2
- PRR4 | c.342A>G p.E114= | Silent (SNP) | VAF 146/372 reads (39%) | catalogued as COSV57392639; called by muse, mutect2
- SLC36A1 | c.75G>A p.P25= | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as rs200439772; called by muse, mutect2, varscan2
- SPEF1 | c.174C>T p.P58= | Silent (SNP) | VAF 57/154 reads (37%) | catalogued as rs754273044, COSV65726701; called by muse, mutect2, varscan2
- C7orf66 | n.364del | RNA (DEL) | VAF 89/259 reads (34%) | called by mutect2, pindel, varscan2
- CRIP3 | c.*114T>C | 3'UTR (SNP) | VAF 51/136 reads (38%) | catalogued as COSV51485997; called by muse, mutect2, varscan2
